Somatic mutation profile of tumor specimen TARGET-10-PAPZTL-09A (aliquot TARGET-10-PAPZTL-09A-01D) from TARGET case TARGET-10-PAPZTL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,773 days).
Specimen TARGET-10-PAPZTL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c6040d9-635a-45d7-82e9-5d774cdcbeee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPZTL-10A (Blood Derived Normal), aliquot TARGET-10-PAPZTL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22e38121-257c-40ff-8de8-3daf8941129d

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Intron 5, Nonsense Mutation 3, Silent 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP7B1 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs760486227; called by muse, mutect2, varscan2
- DIRAS2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV65370078; called by muse, mutect2, varscan2
- GHR | c.439G>C p.V147L | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100050510; called by muse, mutect2
- MYLK | c.3937G>A p.E1313K | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as COSV60604832; called by muse, mutect2, varscan2
- NBAS | c.6436G>A p.D2146N | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV55716877; called by muse, mutect2, varscan2
- SPINK5 | c.1315G>T p.E439* | Nonsense Mutation (SNP) | VAF 33/94 reads (35%) | catalogued as COSV56259771; called by muse, mutect2, varscan2
- TMEM169 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs201548005, COSV99824300; called by muse, mutect2, varscan2
- XIRP2 | c.6998C>T p.S2333L (on ENST00000628543; = p.S2508L on NM_152381.6) | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV54690632; called by muse, mutect2
- ARFGEF2 | c.2116G>C p.E706Q | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- CES5A | c.293C>G p.S98* | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- CLCN7 | c.1185G>C p.L395F | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.713); called by muse, mutect2
- CPB1 | c.696T>A p.F232L | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDX25 | c.108G>C p.K36N | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.06); called by muse, mutect2
- DNM3 | c.159C>A p.G53= | Splice Region (SNP) | VAF 2/8 reads (25%) | called by muse, mutect2
- HERC2 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MLLT10 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 34/102 reads (33%) | called by muse, mutect2, varscan2
- MPDZ | c.2605G>A p.D869N | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- MTMR12 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2
- OGFOD1 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.92); called by muse, mutect2
- POU5F1B | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- RAD51AP2 | c.674A>G p.N225S | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- RASGRP1 | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- SRRM2 | c.6269C>G p.S2090C | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- TENM2 | c.960C>A p.F320L (on ENST00000518659 / NM_001122679.2; = p.F129L on NM_001080428.3) | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TP53BP1 | c.2804G>C p.R935T | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- ZNF385B | c.1272G>A p.M424I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- RESP18 | c.306A>G p.L102= | Silent (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- SEC24D | c.439C>T p.L147= | Silent (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- CFAP74 | c.2176+279C>T | Intron (SNP) | VAF 44/82 reads (54%) | catalogued as rs756864654; called by muse, mutect2, varscan2
- MTHFD1 | c.2280-15A>T | Intron (SNP) | VAF 8/13 reads (62%) | called by muse, varscan2
- NRBP2 | c.355-17G>C | Intron (SNP) | VAF 37/79 reads (47%) | called by muse, mutect2, varscan2
- RAPGEF3 | c.6+156_6+157insGGG | Intron (INS) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- TSPAN11 | c.84+41G>A | Intron (SNP) | VAF 35/143 reads (24%) | called by muse, mutect2, varscan2
